Somatic mutation profile of tumor specimen TCGA-DJ-A3UU-01A (aliquot TCGA-DJ-A3UU-01A-11D-A22D-08) from TCGA case TCGA-DJ-A3UU, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage III; Age at diagnosis: 49.1 years (17,919 days).
Specimen TCGA-DJ-A3UU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 20672902-a8e4-4831-9070-208d5d2c73f0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DJ-A3UU-10A (Blood Derived Normal), aliquot TCGA-DJ-A3UU-10A-01D-A22D-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2cffeeab-e0c5-48b6-bd75-0f07b40ba606

The open-access MAF lists 5 somatic variants for this specimen: 5 protein-altering or splice-affecting.
By variant classification: Missense Mutation 4, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 33/115 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ALG13 | c.796G>A p.V266I | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.997); catalogued as COSV52645985; called by muse, mutect2, varscan2
- RAB41 | c.197T>C p.I66T (on ENST00000374473 / NM_001363807.1; = p.I65T on NM_001032726.3) | Missense Mutation (SNP) | VAF 10/268 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV52105571; called by muse, mutect2
- RNF170 | c.470A>C p.N157T | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as COSV53568617; called by muse, mutect2, varscan2
- UTP14C | c.44_45del p.Q15Rfs*14 | Frame Shift Del (DEL) | VAF 18/63 reads (29%) | called by mutect2, pindel, varscan2
